Gene-level copy-number profile of tumor specimen ALCH-B2WN-TTP1-A from ALCHEMIST case ALCH-B2WN, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: female; Primary diagnosis: Adenocarcinoma, NOS; Age at diagnosis: 63.1 years (23,050 days).
Specimen ALCH-B2WN-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file c265ec9b-0044-49e7-9cfa-291aff6b4552.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator ALCH-B2WN-NB1-A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 2,217 have no estimate.
https://portal.gdc.cancer.gov/files/18555555-ff2d-4c21-9fc2-4d27f41a7274

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 1: 134; copy number 2: 55,928; copy number 3: 2,341; copy number 6: 3.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 3 genes in 2 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr22:18,715,815–18,719,341, 1 gene, copy number 6: PPP1R26P4.
- chr22:18,846,811–18,861,049, 2 genes, copy number 6: AC008132.1, BCRP7.

Autosomal genes at a single copy (total copy number 1): 134. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
